Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041120-09A.1 (aliquot TARGET-15-SJMPAL041120-09A.1-01D) from TARGET case TARGET-15-SJMPAL041120, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,407 days).
Specimen TARGET-15-SJMPAL041120-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc4513ca-76b4-4374-ae64-a24d31b9a2ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041120-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041120-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9fc07cd-3bf3-405f-ace9-9de26c16860c

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Nonsense Mutation 4, Silent 3, Intron 3, Frame Shift Ins 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNM2 | c.1609G>A p.G537S (on ENST00000355667 / NM_001005360.3; = p.G533S on NM_004945.3) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as rs121909093, CM073019, COSV99042600; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLDN20 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886427143, COSV65697647; called by muse, mutect2
- DCLK2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1228169229; called by muse, mutect2, varscan2
- HOOK2 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763027128, COSV53401485; called by muse, mutect2, varscan2
- PLPPR2 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52259508; called by muse, varscan2
- PSMB6 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs775892066; called by muse, mutect2
- TMPRSS5 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55423790, COSV55425485; called by muse, mutect2
- WT1 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | catalogued as rs547775568; called by muse, mutect2, varscan2
- YY1 | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216976; called by muse, mutect2, varscan2
- CIRBP | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- CPEB4 | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); called by muse, varscan2
- EIF2S3 | c.381C>A p.V127= | Splice Region (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- FDXR | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT14 | c.1118C>A p.A373D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- GOLGA4 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- KAT6B | c.4628dup p.A1544Gfs*27 | Frame Shift Ins (INS) | VAF 36/200 reads (18%) | called by mutect2, pindel, varscan2
- NELL1 | c.1506C>A p.C502* | Nonsense Mutation (SNP) | VAF 46/147 reads (31%) | called by muse, mutect2, varscan2
- PHF6 | c.901_903del p.Y301del | In Frame Del (DEL) | VAF 17/106 reads (16%) | called by pindel*, varscan2
- PSMA1 | c.255-1G>T p.X85_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- PTPA | c.677T>A p.V226D (on ENST00000337738 / NM_178001.2; = p.V191D on NM_021131.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- UPF3B | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- WT1 | c.900C>G p.Y300* | Nonsense Mutation (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- FMN2 | c.1374C>T p.A458= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- OR2F1 | c.207C>T p.V69= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs760045594, COSV101231307; called by muse, mutect2, varscan2
- SPON1 | c.789C>A p.G263= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- CLPTM1 | c.1038+111C>A | Intron (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- PMPCB | c.1405+23T>C | Intron (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-26378G>A | Intron (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
